Somatic mutation profile of tumor specimen MP2PRT-PATJJR-TMP1-A (aliquot MP2PRT-PATJJR-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJJR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (614 days).
Specimen MP2PRT-PATJJR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c27cc2-777b-47e8-b65d-9df5d789f5aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJJR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJJR-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16a7e98f-f70f-419f-83b2-9b57543116eb

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555038090, COSV63293359; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 160/394 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TMEM134 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 175/392 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs371527066, COSV104411577; called by muse, mutect2, varscan2
- MYOCD | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R5D | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 172/553 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- AL354761.1 | c.54G>A p.A18= | Silent (SNP) | VAF 137/377 reads (36%) | catalogued as rs1449285376; called by muse, mutect2, varscan2
- BICRA | c.4596C>T p.P1532= | Silent (SNP) | VAF 32/616 reads (5%) | catalogued as rs1016180643; called by muse, mutect2
- ESPL1 | c.4824G>A p.L1608= | Silent (SNP) | VAF 91/391 reads (23%) | catalogued as COSV57760670; called by muse, mutect2
- OR6B3 | c.63A>G p.P21= | Silent (SNP) | VAF 18/512 reads (4%) | called by muse, mutect2
